Somatic mutation profile of tumor specimen TCGA-WK-A8XY-01A (aliquot TCGA-WK-A8XY-01A-11D-A37C-09) from TCGA case TCGA-WK-A8XY, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 53.7 years (19,597 days).
Specimen TCGA-WK-A8XY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7c2f225-a051-412f-b128-74117fd6b775.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WK-A8XY-10A (Blood Derived Normal), aliquot TCGA-WK-A8XY-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c3302c0-6434-4e49-bce5-7747fa6789aa

The open-access MAF lists 39 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 25, Silent 6, Nonsense Mutation 5, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 33/35 reads (94%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC011462.1 | c.155C>G p.P52R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.328); catalogued as COSV100640987; called by muse, mutect2, varscan2
- ADAMTS6 | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV101124616; called by muse, mutect2, varscan2
- ADCY10 | c.4355G>C p.R1452T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100896529; called by muse, mutect2, varscan2
- AP2A1 | c.1369G>C p.V457L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV100756093; called by muse, mutect2, varscan2
- ATP5F1C | c.687C>A p.Y229* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100184249; called by muse, mutect2, varscan2
- BNC1 | c.1700T>A p.M567K | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV100596870; called by muse, mutect2, varscan2
- CBX4 | c.1606T>C p.F536L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV99490175; called by muse, mutect2, varscan2
- DEPDC1B | c.306C>A p.H102Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99409335; called by muse, mutect2, varscan2
- DNM1 | c.1427T>C p.M476T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.111); catalogued as COSV100359395; called by muse, mutect2, varscan2
- DOCK3 | c.1985T>A p.L662* | Nonsense Mutation (SNP) | VAF 35/81 reads (43%) | catalogued as COSV99808858; called by muse, mutect2, varscan2
- F13A1 | c.458G>C p.C153S | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); catalogued as COSV99342057; called by muse, mutect2, varscan2
- GAS2L3 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99902663; called by muse, mutect2
- GYPC | c.85A>G p.M29V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV52144786, COSV99391576; called by muse, mutect2, varscan2
- HOXC13 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 28/35 reads (80%) | catalogued as COSV99673233; called by muse, mutect2, varscan2
- INTS6L | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100878005; called by muse, mutect2, varscan2
- LRP2 | c.9821G>A p.S3274N | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as rs780200412, COSV55575479; called by muse, mutect2, varscan2
- MAGEB6B | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV101301710; called by muse, mutect2, varscan2
- MDP1 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV99164576, COSV99164584; called by muse, mutect2, varscan2
- MMP10 | c.728C>G p.T243R | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.802); catalogued as COSV99666310; called by muse, mutect2, varscan2
- PIGQ | c.1198T>G p.Y400D | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99215646; called by muse, mutect2, varscan2
- POU3F2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100098935; called by muse, mutect2, varscan2
- PTCHD1 | c.1319T>A p.F440Y | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV101037197; called by muse, mutect2, varscan2
- PTEN | c.89del p.P30Qfs*24 | Frame Shift Del (DEL) | VAF 17/27 reads (63%) | catalogued as COSV64292392; called by mutect2, pindel, varscan2
- SH3TC1 | c.2485G>C p.V829L | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99794334; called by muse, mutect2, varscan2
- SLC19A2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs370511652; called by muse, mutect2, varscan2
- SYTL1 | c.1531C>A p.R511S (on ENST00000543823; = p.R499S on NM_032872.3) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100539048; called by muse, mutect2, varscan2
- TRPM3 | c.1273G>T p.E425* (on ENST00000357533 / NM_001366142.2; = p.E270* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100676482, COSV62581878; called by muse, mutect2, varscan2
- TTC37 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.299); catalogued as COSV100706312; called by muse, mutect2, varscan2
- TTN | c.16544T>C p.I5515T (on ENST00000591111; = p.I4588T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | PolyPhen benign (0.066); catalogued as rs1222549953, COSV100592184; called by muse, mutect2
- WASHC1 | c.1254G>A p.M418I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs1394735300; called by mutect2, varscan2
- ZNF574 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV55906492, COSV99725688; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1739del p.G580Afs*7 | Frame Shift Del (DEL) | VAF 15/21 reads (71%) | called by mutect2, varscan2
- EVPL | c.4587C>T p.D1529= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs1231161348, COSV100043844; called by muse, mutect2, varscan2
- GAK | c.1947C>A p.S649= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV100033080; called by muse, varscan2
- GAK | c.1725C>A p.I575= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100033081; called by muse, mutect2, varscan2
- MUC16 | c.11157T>A p.T3719= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV101197851; called by muse, mutect2
- NFATC3 | c.3123G>A p.G1041= | Silent (SNP) | VAF 19/19 reads (100%) | catalogued as COSV52177199; called by muse, mutect2, varscan2
- SMG8 | c.897G>A p.R299= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99958646; called by muse, mutect2, varscan2
